Somatic mutation profile of tumor specimen TCGA-ED-A5KG-01A (aliquot TCGA-ED-A5KG-01A-11D-A27I-10) from TCGA case TCGA-ED-A5KG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.9 years (22,258 days).
Specimen TCGA-ED-A5KG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59be2c21-3918-4e10-8a80-542f4700f7c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A5KG-10A (Blood Derived Normal), aliquot TCGA-ED-A5KG-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65335a98-9078-4fcd-94b6-62f78f734743

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 10, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1409276980, COSV61263512; called by muse, mutect2
- CA4 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV56281571; called by muse, mutect2
- CSMD1 | c.7190C>T p.T2397I (on ENST00000520002; = p.T2396I on NM_033225.6) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as rs1371744003, COSV59327474; called by muse, mutect2
- DNAH17 | c.10100G>A p.G3367D | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67754866; called by muse, mutect2
- IRGC | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs764477711, COSV54983093; called by muse, mutect2
- MUC16 | c.37126T>A p.S12376T | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.031); catalogued as COSV101200013; called by muse, mutect2
- MYO5B | c.3606G>T p.R1202S | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV53219373; called by muse, mutect2
- OR11A1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs745945077, COSV65820876; called by muse, mutect2
- RHBDD2 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV50087050; called by muse, mutect2
- SLC13A4 | c.1339C>A p.L447M | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV62461180; called by muse, mutect2
- SRC | c.1367C>G p.T456S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV62439911; called by muse, mutect2
- AGMAT | c.450A>C p.A150= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV65435889; called by muse, mutect2, varscan2
- ASIC2 | c.432G>A p.K144= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV63308134; called by muse, mutect2
- CNTN2 | c.2751C>A p.G917= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV59350143; called by muse, mutect2
- DMD | c.8319C>A p.V2773= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV58912349; called by muse, mutect2
- HEATR3 | c.570G>T p.V190= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV53529352; called by muse, mutect2
- NIPBL | c.4752C>T p.L1584= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV56951782; called by muse, mutect2, varscan2
- ODF1 | c.424C>A p.R142= | Silent (SNP) | VAF 13/244 reads (5%) | catalogued as COSV53431558, COSV53432595; called by muse, mutect2
- OR51A4 | c.471G>T p.L157= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as rs1482545778, COSV66749503, COSV66750147; called by muse, mutect2
- OR8B4 | c.693G>A p.E231= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as rs1280391444, COSV62069781; called by muse, mutect2
- RYR2 | c.12081G>A p.T4027= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV63686959; called by muse, mutect2
- MGAM | c.4618+5599G>A | Intron (SNP) | VAF 13/115 reads (11%) | catalogued as rs373367889; called by muse, mutect2, varscan2
